Somatic mutation profile of tumor specimen 1990853a-0e82-40b3-a025-91cdc1 (aliquot 1990853a-0e82-40b3-a025-91cdc1_D6) from CPTAC case 01BR027, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 79.9 years (29,199 days).
Specimen 1990853a-0e82-40b3-a025-91cdc1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 68f3e5d3-2d22-4550-81bd-81de61eccd9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 71f40378-962e-4a4b-b0de-6ec414 (Blood Derived Normal), aliquot 71f40378-962e-4a4b-b0de-6ec414_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffcff1a2-52ff-4e08-a784-05ec69ab107c

The open-access MAF lists 146 somatic variants for this specimen: 96 protein-altering or splice-affecting, 30 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 30, Intron 14, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 4, 3'UTR 3, Splice Region 2, Frame Shift Ins 1, RNA 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 83/378 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.3563C>T p.A1188V (on ENST00000614293; = p.A1158V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/539 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778927183; called by muse, mutect2, varscan2
- ASAP1 | c.3315+1G>T p.X1105_splice | Splice Site (SNP) | VAF 25/223 reads (11%) | catalogued as COSV63053460; called by muse, mutect2, varscan2
- C14orf132 | c.305A>G p.N102S (on ENST00000553782 / NM_001289139.2; = p.N71S on NM_001252507.3) | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs980264501; called by muse, mutect2
- C1orf146 | c.350G>C p.R117P | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV64860559; called by muse, mutect2
- CDK2AP1 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV53517201; called by muse, mutect2, varscan2
- CLUH | c.3036C>G p.Y1012* (on ENST00000435359; = p.Y1051* on NM_015229.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/227 reads (8%) | catalogued as COSV101425670, COSV70928243; called by muse, mutect2
- COG4 | c.2041G>A p.G681S | Missense Mutation (SNP) | VAF 66/787 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs547599836; called by muse, mutect2
- CSF3 | c.228C>A p.H76Q | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1413890446; called by muse, mutect2, varscan2
- DNMT3L | c.345-1G>C p.X115_splice | Splice Site (SNP) | VAF 14/125 reads (11%) | catalogued as rs537042586; called by muse, mutect2, varscan2
- EDEM3 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.899); catalogued as rs1028624037; called by muse, mutect2
- EIF2B5 | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 47/459 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.199); catalogued as rs774068091; called by muse, mutect2, varscan2
- EIF3B | c.2148G>C p.Q716H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV62802657; called by muse, mutect2
- EVC | c.1979C>T p.T660M | Missense Mutation (SNP) | VAF 88/837 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.799); catalogued as rs550100215, COSV53828779; called by muse, mutect2, varscan2
- HECW1 | c.94C>T p.R32* | Nonsense Mutation (SNP) | VAF 72/306 reads (24%) | catalogued as COSV67821120; called by muse, mutect2, varscan2
- HERC2 | c.5767A>G p.K1923E | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs766553462; called by muse, mutect2
- HSPA14 | c.1339G>C p.D447H | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as rs1305107822, COSV65685213; called by muse, mutect2
- INTS14 | c.80G>A p.R27H (on ENST00000313182 / NM_001366360.2; = p.X27_splice on NM_001207058.3) | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs746692780; called by muse, mutect2, varscan2
- LEPR | c.1889A>T p.Y630F | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.488); catalogued as COSV60762367; called by muse, mutect2, varscan2
- NBEA | c.7660C>T p.Q2554* | Nonsense Mutation (SNP) | VAF 7/109 reads (6%) | catalogued as COSV59807318; called by muse, mutect2
- OCRL | c.2556C>A p.Y852* | Nonsense Mutation (SNP) | VAF 57/502 reads (11%) | catalogued as CD086662; called by muse, mutect2, varscan2
- PROSER3 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs748463002; called by muse, mutect2, varscan2
- RBL2 | c.2225C>T p.T742M | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs777931235, COSV50873696; called by muse, mutect2
- SART1 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56714377; called by muse, mutect2, varscan2
- SEC24D | c.2843C>G p.S948C | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV54879609; called by muse, mutect2, varscan2
- SKI | c.1767G>A p.Q589= | Splice Region (SNP) | VAF 8/203 reads (4%) | catalogued as rs1325763646; called by muse, mutect2
- SMARCE1 | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52860747; called by muse, mutect2
- SNCA | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as COSV61132952; called by muse, mutect2
- STARD9 | c.10459A>G p.M3487V | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1456026557; called by muse, mutect2, varscan2
- THEG | c.931G>C p.D311H | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV61073887; called by muse, mutect2
- TMEM117 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.99); catalogued as rs1343953327; called by muse, mutect2, varscan2
- TSPAN19 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs777078565, COSV101468087; called by muse, mutect2, varscan2
- TTN | c.69487A>G p.I23163V (on ENST00000591111; = p.I15739V on NM_003319.4) | Missense Mutation (SNP) | VAF 30/291 reads (10%) | PolyPhen benign (0.001); catalogued as rs544547448; called by muse, mutect2, varscan2
- ABCA10 | c.3947C>G p.A1316G | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, varscan2
- ABRACL | c.239A>C p.Q80P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2
- AKNA | c.726C>G p.H242Q | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by mutect2, varscan2
- ANKRD30B | c.4002G>C p.Q1334H | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0); called by mutect2, varscan2
- APOB | c.4451T>A p.V1484D | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); called by muse, mutect2
- ARSF | c.797T>C p.I266T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- BNC2 | c.1708C>G p.P570A | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.991); called by muse, mutect2
- C5 | c.5013C>G p.I1671M | Missense Mutation (SNP) | VAF 26/327 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2
- CA5A | c.855A>C p.Q285H | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAPRIN2 | c.2048C>T p.T683I | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2
- CARD6 | c.2629G>C p.E877Q | Missense Mutation (SNP) | VAF 22/477 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CASKIN2 | c.1544A>G p.Y515C | Missense Mutation (SNP) | VAF 72/354 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH7 | c.1424T>C p.I475T | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- CEP350 | c.3018G>C p.L1006F | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.566); called by muse, mutect2
- CILK1 | c.1052A>G p.Y351C | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CPED1 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- CRX | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 57/384 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- DDOST | c.1085del p.P362Lfs*3 (on ENST00000415136; = p.P345Lfs*3 on NM_005216.5) | Frame Shift Del (DEL) | VAF 19/176 reads (11%) | called by mutect2, pindel, varscan2
- DISP1 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.468); called by muse, mutect2
- DUOXA1 | c.290C>G p.A97G | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.086); called by muse, mutect2
- DUS3L | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- EIF4A2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, varscan2
- ENO3 | c.1140C>G p.F380L | Missense Mutation (SNP) | VAF 115/436 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.849); called by mutect2, varscan2
- ETNPPL | c.1489C>G p.L497V | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); called by muse, mutect2
- FAM160A1 | c.2693A>G p.N898S | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GBA | c.542T>G p.F181C | Missense Mutation (SNP) | VAF 25/784 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GUF1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- HTR1A | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 20/352 reads (6%) | called by muse, mutect2
- IL17RD | c.1118dup p.V374Rfs*15 | Frame Shift Ins (INS) | VAF 16/143 reads (11%) | called by mutect2, pindel, varscan2
- KIAA0586 | c.4222_4223del p.L1408Dfs*6 (on ENST00000619416 / NM_001244190.2; = p.L1347Dfs*6 on NM_014749.5) | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | called by mutect2, pindel, varscan2
- KIF11 | c.1795C>T p.H599Y | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2
- KRT37 | c.932A>C p.E311A | Missense Mutation (SNP) | VAF 76/214 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC47 | c.1643_1644delinsA p.L548Qfs*15 | Frame Shift Del (DEL) | VAF 22/218 reads (10%) | called by pindel, varscan2*
- LRRC49 | c.1802C>G p.T601R | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- MEA1 | c.459_471del p.V155Lfs*47 | Frame Shift Del (DEL) | VAF 8/83 reads (10%) | called by mutect2, pindel
- NSMCE4A | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NWD2 | c.4175T>G p.L1392R | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- OR4C16 | c.879A>C p.K293N | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- PFKFB2 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 26/141 reads (18%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALGAPA2 | c.2605T>A p.C869S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- RBM4B | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 39/400 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- RFPL4A | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 40/784 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2
- RPGRIP1 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.112); called by muse, mutect2
- RPGRIP1L | c.1841T>G p.V614G | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); called by muse, mutect2
- SELENOS | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, varscan2
- SLC35A1 | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- SLC35D1 | c.554T>G p.L185R | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- SLC39A9 | c.17C>G p.S6C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- SMAD5 | c.776-1G>C p.X259_splice | Splice Site (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- SOGA1 | c.3842T>G p.L1281R | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SPAG17 | c.2239G>C p.D747H | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.264); called by muse, mutect2
- STAB1 | c.693A>T p.R231= | Splice Region (SNP) | VAF 30/196 reads (15%) | called by mutect2, varscan2
- SYCP2L | c.1023G>T p.W341C | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TBC1D15 | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 30/179 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- TEX44 | c.440C>A p.S147* | Nonsense Mutation (SNP) | VAF 36/358 reads (10%) | called by muse, mutect2, varscan2
- THEMIS | c.240_250+2del p.X80_splice | Splice Site (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel, varscan2
- TLR4 | c.257C>T p.S86F (on ENST00000355622 / NM_138554.5; = p.S46F on NM_003266.4) | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM128 | c.146A>T p.N49I (on ENST00000382753 / NM_001297552.2; = p.N25I on NM_032927.3) | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM24 | c.443C>G p.T148S | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.035); called by muse, mutect2
- UBQLN2 | c.1371G>C p.Q457H | Missense Mutation (SNP) | VAF 22/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- VBP1 | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2
- ZNF350 | c.994T>G p.C332G | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- ZNF84 | c.1105C>G p.H369D | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AL669918.1 | c.2424C>T p.V808= | Silent (SNP) | VAF 16/420 reads (4%) | catalogued as rs373352523, COSV101441054, COSV71270906; called by muse, mutect2
- ASH1L | c.8652A>G p.P2884= (on ENST00000368346 / NM_001366177.2; = p.P2879= on NM_018489.3) | Silent (SNP) | VAF 15/408 reads (4%) | called by muse, mutect2
- CD38 | c.153C>T p.S51= | Silent (SNP) | VAF 31/273 reads (11%) | catalogued as rs763737168, COSV99882627; called by muse, mutect2, varscan2
- CLDN14 | c.198C>A p.I66= | Silent (SNP) | VAF 42/1150 reads (4%) | catalogued as COSV59776362; called by muse, mutect2
- CRYBB2 | c.117C>A p.P39= | Silent (SNP) | VAF 27/473 reads (6%) | called by muse, mutect2
- DYSF | c.2562C>G p.V854= | Silent (SNP) | VAF 42/481 reads (9%) | catalogued as COSV50559033; called by muse, mutect2
- ELSPBP1 | c.318C>T p.F106= | Silent (SNP) | VAF 42/220 reads (19%) | catalogued as rs1047360478, COSV60413632; called by muse, mutect2, varscan2
- EVPL | c.4851G>A p.S1617= | Silent (SNP) | VAF 23/350 reads (7%) | catalogued as rs142844241, COSV101440983; called by muse, mutect2
- GLYCTK | c.324C>T p.G108= | Silent (SNP) | VAF 45/351 reads (13%) | catalogued as rs770294415, COSV99980975; called by muse, mutect2, varscan2
- KRT12 | c.681C>T p.G227= | Silent (SNP) | VAF 84/272 reads (31%) | catalogued as rs775787583, COSV52432860; called by muse, mutect2, varscan2
- LRIG2 | c.996G>A p.V332= | Silent (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- LYST | c.11055C>T p.D3685= | Silent (SNP) | VAF 20/238 reads (8%) | called by muse, mutect2
- MASP2 | c.447G>A p.A149= | Silent (SNP) | VAF 40/338 reads (12%) | catalogued as rs1181755451; called by muse, mutect2
- MYH2 | c.3852G>A p.G1284= | Silent (SNP) | VAF 92/311 reads (30%) | called by muse, mutect2, varscan2
- MYOF | c.378G>A p.P126= | Silent (SNP) | VAF 32/142 reads (23%) | catalogued as rs779836306; called by muse, mutect2, varscan2
- NCKAP1 | c.507A>G p.G169= | Silent (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- NRIP3 | c.357G>C p.V119= | Silent (SNP) | VAF 15/233 reads (6%) | called by muse, mutect2
- OR2AK2 | c.225C>A p.S75= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- PLB1 | c.2496A>G p.Q832= | Silent (SNP) | VAF 16/177 reads (9%) | called by muse, mutect2, varscan2
- POU4F2 | c.840C>A p.G280= | Silent (SNP) | VAF 20/224 reads (9%) | catalogued as rs898241738; called by muse, mutect2
- PPAT | c.1401A>G p.S467= | Silent (SNP) | VAF 15/107 reads (14%) | called by muse, mutect2, varscan2
- PRDM8 | c.336G>C p.L112= | Silent (SNP) | VAF 78/385 reads (20%) | called by muse, mutect2, varscan2
- RXFP3 | c.1251C>G p.P417= | Silent (SNP) | VAF 31/570 reads (5%) | called by muse, mutect2
- SLITRK2 | c.84T>C p.I28= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as COSV59423716; called by muse, mutect2, varscan2
- SOGA1 | c.4857C>G p.T1619= | Silent (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- STRA8 | c.675G>A p.K225= (on ENST00000275764; = p.K203= on NM_182489.2) | Silent (SNP) | VAF 99/623 reads (16%) | called by muse, mutect2, varscan2
- TBC1D10B | c.2160G>A p.E720= | Silent (SNP) | VAF 36/370 reads (10%) | called by muse, mutect2
- THEMIS | c.1074T>G p.A358= | Silent (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- TNNT1 | c.760C>T p.L254= | Silent (SNP) | VAF 23/492 reads (5%) | called by muse, mutect2
- UROC1 | c.1557C>T p.R519= | Silent (SNP) | VAF 230/836 reads (28%) | catalogued as rs1225781280, COSV99331221; called by muse, mutect2, varscan2
- AP002748.5 | c.*13T>A | 3'UTR (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- ASB16 | c.1177-10C>G | Intron (SNP) | VAF 39/264 reads (15%) | called by muse, mutect2, varscan2
- BTBD11 | c.2991+31T>G | Intron (SNP) | VAF 9/177 reads (5%) | called by muse, mutect2
- CCL3L3 | c.76+141C>T | Intron (SNP) | VAF 30/558 reads (5%) | called by muse, mutect2
- CHRNE | c.1327-13G>A | Intron (SNP) | VAF 54/645 reads (8%) | catalogued as rs745934587; called by muse, mutect2
- CYP2B7P | n.699+32G>T | Intron (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- FIG4 | c.1389-34T>G | Intron (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- GTF2I | c.1993+17_1993+19del | Intron (DEL) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- GTF2IRD2P1 | n.2500G>T | RNA (SNP) | VAF 92/614 reads (15%) | called by muse, mutect2, varscan2
- GTPBP3 | chr19:17335016 C>A | 5'Flank (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2, varscan2
- IER3 | c.211-29G>C | Intron (SNP) | VAF 31/233 reads (13%) | called by muse, mutect2, varscan2
- MCF2L | c.368+2290A>G | Intron (SNP) | VAF 12/229 reads (5%) | called by muse, mutect2
- NAP1L4 | c.1035+161C>G | Intron (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
- PTDSS1 | c.*182G>C | 3'UTR (SNP) | VAF 19/154 reads (12%) | called by muse, mutect2, varscan2
- PTPRB | c.1126+18G>A | Intron (SNP) | VAF 9/123 reads (7%) | called by muse, mutect2
- STAR | c.179-17C>G | Intron (SNP) | VAF 28/396 reads (7%) | called by muse, mutect2
- TMCO1 | c.*1453A>C | 3'UTR (SNP) | VAF 36/374 reads (10%) | called by muse, mutect2, varscan2
- TMEM254 | c.88-161G>C | Intron (SNP) | VAF 38/147 reads (26%) | called by mutect2, varscan2
- TMTC1 | c.939-26547C>T | Intron (SNP) | VAF 8/48 reads (17%) | catalogued as rs540316230; called by muse, mutect2, varscan2
- ZSCAN32 | chr16:3382993 G>T | 3'Flank (SNP) | VAF 53/261 reads (20%) | called by muse, mutect2, varscan2
